Somatic mutation profile of tumor specimen TARGET-20-PARASV-03A (aliquot TARGET-20-PARASV-03A-02D) from TARGET case TARGET-20-PARASV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,401 days).
Specimen TARGET-20-PARASV-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e51d4dd3-0cf9-4585-8056-ca0ae590071d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARASV-14A (Bone Marrow Normal), aliquot TARGET-20-PARASV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d986b07c-ddb9-4318-9959-87216bdf7423

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/212 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP7 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1449173091, COSV63422307; called by muse, mutect2, varscan2
- STOX2 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 128/302 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs369084419; called by muse, mutect2, varscan2
